Surgical pathology report (de-identified scan), TCGA case TCGA-CX-7219, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-CX-7219-01A (Primary Tumor).

[page 1 of 7]
TCGA 8004

Final Pathology Diagnosis Report

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Final Pathologic Diagnosis

A) RIGHT LEVEL I (RADICAL NECK DISSECTION):

- Metastatic squamous cell carcinoma in 2 of 4 lymph nodes (2/4).
- Submandibular gland with chronic sialadenitis; negative for neoplasia.

B) RIGHT LEVEL II (RADICAL NECK DISSECTION):

- Metastatic squamous cell carcinoma in 3 of 11 lymph nodes (3/11).

C) RIGHT LEVEL III (RADICAL NECK DISSECTION):

- Metastatic squamous cell carcinoma in 1 of 9 lymph nodes (1/9).
- Positive for extranodal extension.
- Intranodal thyroid tissue consistent with metastatic papillary thyroid carcinoma, follicular variant.

D) RIGHT LEVEL VI (RADICAL NECK DISSECTION):

- Nine lymph nodes negative for neoplasia (0/9).

E) LEFT LEVEL I (RADICAL NECK DISSECTION):

- Metastatic squamous cell carcinoma in 1 of 9 lymph nodes (1/9).
- Submandibular gland with chronic sialadenitis and atrophy; negative for neoplasia.

F) LEFT LEVEL II (RADICAL NECK DISSECTION):

- Metastatic squamous cell carcinoma in 5 of 14 lymph nodes (5/14).

G) LEFT LEVEL III (RADICAL NECK DISSECTION):

- Seven lymph nodes negative for neoplasia (0/7).

H) LEFT LEVEL VI (RADICAL NECK DISSECTION):

- Nine lymph nodes negative for neoplasia (0/9).

[page 2 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

I) BILATERAL SUBMENTAL LYMPH NODES (RADICAL NECK DISSECTION):

- Metastatic squamous cell carcinoma in 2 of 4 lymph nodes (2/4).
- Positive for extranodal extension.

J) TONGUE, FLOOR OF MOUTH AND MANDIBLE (COMPOSITE RESECTION OF FLOOR OF MOUTH, SEGMENTAL MANDIBULECTOMY, AND TOTAL GLOSSECTOMY):

- Well to moderately differentiated infiltrating squamous cell carcinoma (see synoptic report).

K) DEEP TONGUE MARGIN (BIOPSY):

- Negative for neoplasia.

L) ANTERIOR TONGUE (BIOPSY):

- Negative for neoplasia.

M) LEFT LATERAL (BIOPSY):

- Negative for neoplasia.

N) RIGHT LATERAL (BIOPSY):

- Negative for neoplasia.

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Resident:

[page 3 of 7]
Final Pathology Diagnosis Report

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Synoptic Report

J: Upper Aerodigestive Tract, Macroscopic

SPECIMEN TYPE:

Resection (specify type): Composite resection floor of mouth, segmental mandibulectomy, total glossectomy and bilateral radical neck dissection.

TUMOR SITE:

Oral Cavity

TUMOR SIZE:

Greatest dimension: 7 cm

*Additional dimensions: 6 x 3 cm

J: UPPER AERODIGESTIVE TRACT, MICRO - MCGH

HISTOLOGIC TYPE:

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2: Moderately differentiated

PRIMARY TUMOR (pT): Lip and Oral Cavity:

pT4a: Oral Cavity: Tumor invades adjacent structures (eg, through cortical bone, into deep [extrinsic] muscle of tongue [genioglossus, hyoglossus, palatoglossus, and styloglossus], maxillary sinus, skin of face)

PRIMARY TUMOR (pT): Oropharynx

REGIONAL LYMPH NODES (pN): All Aerodigestive Sites Except Nasopharynx:

pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension

Number examined: 76

Number involved: 14

*EXTRA-CAPSULAR EXTENSION OF NODAL TUMOR:

*Present

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Margins uninvolved by tumor

Distance of tumor from closest margin: 0.6 mm

Specify margin, if possible: Anterior gingival

*VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

*Present

PERINEURAL INVASION:

Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

[page 4 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Metastatic thyroid carcinoma (follicular variant of papillary) in right level III lymph node.

Intraoperative Diagnosis

K1: Negative for carcinoma.

L1: Negative for carcinoma.

M1: Negative for carcinoma. No in situ/ invasive carcinoma.

N1: Negative for carcinoma.

Clinical History

male with tongue squamous cell carcinoma.

Pre/Post-operative Diagnosis

Tongue squamous cell carcinoma cancer.

Gross Anatomic Description

(Dictated by

Specimens received in fourteen containers.

Specimen A: Designated "right level I" is received in formalin labeled with the patient's name and "right level I". Specimen consists of two fragments of pink/ tan soft tissue measuring 3.5 x 2.5 x 1 cm and 2 x 1.5 x 0.8 cm. Cut surfaces show tan lobulated soft cut surfaces (possible submandibular gland) and two possible lymph nodes, each measuring 0.5 x 0.5 x 0.5 cm. Section code: A1 – possible two lymph nodes bisected; A2 – soft tissue bisected (possible lymph node); A3 – representative sections from possible submandibular gland.

Specimen B: Designated "right level II" is received in formalin labeled with the patient's name and "right level II". Specimen consists of two fragments of fibroadipose tissue measuring 5 x 3 x 1.5 cm and 3 x 1 x 0.4 cm. Multiple lymph nodes are dissected.

Section code: B1 – individual lymph node; B2 – bisected lymph node; B3–B4 – one bisected lymph node; B5 – soft tissue bisected (possible lymph node).

Specimen C: Designated "right level III" is received in formalin labeled with the patient's name and "right level III". Specimen consists of a pink/ tan fibroadipose tissue fragment measuring 5 x 1.5 x 0.3 cm. The specimen is dissected for lymph nodes.

[page 5 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Four possible lymph nodes dissected.

Section code: C1 – individual lymph nodes; C2 – one bisected lymph node; C3 – one bisected lymph node.

Specimen D: Designated "right level VI" is received in formalin labeled with the patient's name and "right level VI". Specimen consists of a pink/ yellow/ tan fibroadipose tissue fragment measuring 3 x 2 x 0.4 cm. The specimen is dissected for lymph nodes.

Section code: D1 – multiple possible lymph nodes; D2 – two lymph nodes bisected.

Specimen E: Designated "left level I" is received in formalin labeled with the patient's name and "left level I". Specimen consists of pink/ tan soft tissue fragments measuring 4.5 x 2.5 x 0.7 cm and 3 x 2 x 0.2 cm. The larger fragment has yellow/ tan lobulated soft cut surfaces. The smaller fragment consists of three possible lymph nodes.

Section code: E1 – one lymph node bisected; E2 – multiple lymph nodes; E3 – one lymph node bisected; E4 – representative section from the larger fragment (possible salivary gland).

Specimen F: Designated "left level II" is received in formalin labeled with the patient's name and "left level II". Specimen consists of a pink fibroadipose tissue fragment measuring 7 x 3.5 x 1 cm. Four matted lymph nodes and one non-matted lymph node are dissected. The matted lymph nodes range in size from 1.5 x 1.5 x 0.5 cm to 4 x 2 x 1 cm. The non-matted lymph node measures 1.8 x 1 x 0.3 cm. Representative sections are submitted.

Section code: F1–F3 – largest matted lymph node entirely submitted; F4 – second largest matted lymph node submitted entirely; F5 – third largest matted lymph node bisected and submitted entirely; F6 – smallest matted lymph node bisected and submitted entirely; F7 – one lymph node bisected.

Specimen G: Designated "left level III" is received in formalin labeled with the patient's name and "left level III". Specimen consists of fibroadipose tissue fragment measuring 4.5 x 1 x 0.4 cm. The specimen is dissected for lymph nodes. All of the dissected lymph nodes are submitted.

Section code: G1-G2 – one bisected lymph node; G3 – multiple possible lymph nodes.

Specimen H: Designated "left level VI" is received in formalin labeled with the patient's name and "left level VI". Specimen consists of a purple soft tissue fragmented admixed with adipose tissue measuring 5.5 x 1.5 x 0.5 cm. The specimen is dissected for multiple lymph nodes.

Section code: H1-H2 – multiple lymph nodes.

Specimen I: Designated "bilateral submental lymph node" is received in formalin labeled with the patient's name and "bilateral submental lymph node". Specimen consists of a soft tissue fragmented measuring 3.5 x 2.5 x 1.5 cm. Two lymph nodes measuring 2.5 x 1.5 x 1 cm and 1.5 x 1.0 x 0.4 cm are dissected.

Section code: I1 – bisected portion of the largest lymph node; I2 – bisected smaller lymph node.

Specimen J: Designated "composite, mandibulectomy glossectomy and floor of mouth" is received in formalin labeled with the patient's name and "composite, mandibulectomy glossectomy and floor of mouth ". Specimen consists of a

[page 6 of 7]
Final Pathology Diagnosis Report

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

mandibulectomy specimen with attached tongue and floor of mouth measuring 10 cm from anterior to posterior, 7.5 cm from right to left and 8 cm in height. The jaw measures 15 cm in total length, 4.8 cm in width and 1.5 cm in thickness. Four teeth are noted. The inferior aspect of the tongue has a white firm irregular shaped mass measuring 7 x 6 x 3 cm. The mass is located 0.6 cm from the closest posterior margin and 0.6 cm from the closest inferior margin. The tumor grossly extends into the mid anterosuperior region of the mandible and into the attached portion of midanterior gingiva. Representative sections are submitted. Sections of bone are submitted following decalcification. Gross photographs are taken.

Inking code: Black – posterior; Red – anterior; Green – lateral, inferior.

Section code: J1 – J3 – anterior aspect of gingiva midline to lateral right side; J4-J7 – anterior aspect of gingiva midline to lateral left side; J8-J10 – tumor with closest posterior margin J11 – inferior margin; J12 – representative sections of tumor; J13 – J14 – anterior portion of body of mandible; J15 – left ramus margin; J16 – right ramus margin; J17-tumor with inferior gingival mucosa; J18 – possible tumor with the closest inferior margin.

Specimen K: Designated "deep tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "deep tongue margin". Specimen consists of a fragment of red/ tan soft tissue measuring 1.5 x 1 x 0.3 cm. The entire specimen is submitted for frozen section diagnosis.

Section code: K1 – frozen section control.

Specimen L: Designated "anterior tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "anterior tongue margin" Specimen consists of three tan soft tissue fragments measuring 0.4 x 0.4 x 0.7 cm, 1 x 0.4 x 0.2 cm and 3 x 0.7 x 0.3 cm. The largest fragment is bisected. All are submitted for frozen section diagnosis.

Section code: L1 – L2 - frozen section diagnosis.

Specimen M: Designated "left lateral" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left lateral". Specimen consists of three tan soft tissue fragments measuring 0.5 x 0.3 x 0.2 cm, 1.5 x 0.4 x 0.2 cm and 1.5 x 0.3 x 0.4 cm. The specimen is entirely submitted for frozen section diagnosis.

Section code: M1 – frozen section control.

Specimen N: Designated "right lateral" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left lateral". Specimen consists of four tan/ red soft tissue fragments measuring 0.4 x 0.2 x 0.1 cm, 0.5 x 0.2 x 0.1 cm, 0.6 x 0.5 x 0.2 cm and 0.9 x 0.4 x 0.2 cm respectively. The specimen is entirely submitted for frozen section diagnosis.

Section code: N1 – frozen section control.

[page 7 of 7]
I n t r a o p e r a t i v e D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Intraoperative Diagnosis

K1: Negative for carcinoma.

L1: Negative for carcinoma.

M1: Negative for carcinoma. No in situ/ invasive carcinoma.

N1: Negative for carcinoma.

Source: NCI Genomic Data Commons file 892bb853-f4d7-447a-b716-10023862c6eb (TCGA-CX-7219.27634A8C-1A8A-4340-9A45-1D7A7E5F4D9A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).